Somatic mutation profile of tumor specimen ASCProject_0098_T1_WES (aliquot ASCProject_0098_T1_WES_1) from CMI case ASCProject_0098, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: male; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 79.0 years (28,855 days).
Specimen ASCProject_0098_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brow; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 71ce06e8-450b-4c52-8627-30721ffded98.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0098_SALIVA (Saliva), aliquot ASCProject_0098_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f2e134ff-d7eb-4726-9ab8-958e6598e12b

The open-access MAF lists 1,111 somatic variants for this specimen: 637 protein-altering or splice-affecting, 338 silent, 136 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 570, Silent 338, Intron 72, Nonsense Mutation 31, RNA 26, Splice Region 22, 5'Flank 14, Splice Site 11, 5'UTR 10, 3'UTR 10, 3'Flank 4, Frame Shift Del 3.

Variants (750 of 1,111; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1580T>G p.V527G (on ENST00000288602 / NM_001374244.1; = p.V487G on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 89/177 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs397516893, CM071573, COSV56274656; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.4636C>T p.P1546S | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.034); catalogued as rs776200971, COSV101036453; called by muse, mutect2, varscan2
- ABCA1 | c.1439C>T p.S480F | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.092); catalogued as rs755728918, COSV66067798; called by muse, mutect2, varscan2
- ABCD2 | c.1802C>T p.A601V | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.531); catalogued as rs770550941, COSV58053942; called by muse, mutect2, varscan2
- ABCD2 | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV58053915; called by muse, mutect2
- ABRA | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.123); catalogued as rs1301517822, COSV100357447; called by muse, mutect2, varscan2
- ACE | c.2450-1G>A p.X817_splice | Splice Site (SNP) | VAF 33/97 reads (34%) | catalogued as COSV52013925; called by muse, mutect2, varscan2
- ADAM28 | c.1729G>A p.G577R | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56098637; called by muse, mutect2, varscan2
- ADAMDEC1 | c.995C>T p.S332L | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749615970; called by muse, mutect2, varscan2
- ADAMTS1 | c.860C>T p.S287L | Missense Mutation (SNP) | VAF 43/172 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1568811671, COSV53173056; called by muse, mutect2, varscan2
- ADAMTS17 | c.3284C>T p.S1095L | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs778582648; called by muse, mutect2, varscan2
- ADCY10 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.506); catalogued as rs563436022, COSV63240227; called by muse, mutect2, varscan2
- ADGRE5 | c.1606C>T p.L536F (on ENST00000242786 / NM_078481.4; = p.L443F on NM_001784.5) | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54390704; called by muse, mutect2, varscan2
- ADGRG4 | c.5303C>T p.S1768F | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV54959950; called by muse, mutect2, varscan2
- ADGRV1 | c.10475C>T p.S3492F | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs375619656, COSV67983969; called by muse, mutect2, varscan2
- AHNAK2 | c.13624C>T p.L4542F | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); catalogued as COSV60924804; called by muse, mutect2, varscan2
- AK9 | c.2143G>A p.E715K | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs370294605; called by muse, mutect2, varscan2
- ALPK2 | c.3529G>A p.A1177T | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.375); catalogued as rs757899771, COSV64492857; called by muse, mutect2, varscan2
- AMHR2 | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV57687262; called by muse, mutect2, varscan2
- ANK1 | c.5060C>T p.P1687L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.118); catalogued as COSV55881000; called by muse, mutect2, varscan2
- ANKRD20A4P | c.1082-1G>A p.X361_splice | Splice Site (SNP) | VAF 26/79 reads (33%) | catalogued as rs1265350651; called by muse, mutect2, varscan2
- ANO6 | c.1358C>T p.T453I | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.051); catalogued as rs1446727751, COSV57663029; called by muse, mutect2, varscan2
- AP3B2 | c.3125G>A p.G1042E (on ENST00000261722; = p.G1036E on NM_004644.5) | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99917183; called by muse, mutect2
- APOBEC1 | c.254C>T p.T85I | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.348); catalogued as COSV99981155; called by muse, mutect2
- APOL1 | c.943G>A p.G315S | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0.024); catalogued as rs780096138; called by muse, mutect2
- ARHGAP21 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1003664842; called by muse, mutect2, varscan2
- ARID1A | c.4687C>T p.P1563S | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.068); catalogued as rs1484432441, COSV100251195; called by mutect2, varscan2
- ARNT2 | c.1585C>T p.P529S | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as rs1429600637, COSV57582718; called by muse, mutect2, varscan2
- ASXL3 | c.2306G>A p.R769K | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV52462666; called by muse, mutect2, varscan2
- ATP1A2 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as rs866493442; called by muse, mutect2, varscan2
- ATP8B4 | c.1883G>A p.R628Q | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs569305697, COSV52725371; called by muse, mutect2, varscan2
- B4GALT6 | c.648G>A p.M216I | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.411); catalogued as rs190821754; called by muse, mutect2, varscan2
- BCORL1 | c.2504C>T p.P835L | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs1380433198, COSV54408280, COSV99498460; called by mutect2, varscan2
- BICD1 | c.868C>T p.H290Y | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as rs777372640, COSV55677767; called by muse, mutect2, varscan2
- BNC1 | c.401C>A p.T134K | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV61757431; called by muse, mutect2, varscan2
- BRINP1 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56303093; called by muse, mutect2, varscan2
- BRINP2 | c.1522G>A p.D508N | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64177196; called by muse, mutect2, varscan2
- BSPRY | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 58/202 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs767724502; called by muse, mutect2, varscan2
- C6orf118 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.085); catalogued as COSV57814865; called by muse, mutect2, varscan2
- CALR3 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.063); catalogued as rs1442412253, COSV54172988; called by muse, mutect2, varscan2
- CAMK2G | c.1274-8C>T | Splice Region (SNP) | VAF 25/55 reads (45%) | catalogued as rs1177644591; called by muse, mutect2, varscan2
- CAMK4 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1386520704, COSV56677300; called by muse, mutect2, varscan2
- CAMSAP1 | c.4438C>T p.H1480Y | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs1252445116; called by muse, mutect2, varscan2
- CASKIN1 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1331380994; called by muse, varscan2
- CATIP | c.921G>A p.K307= | Splice Region (SNP) | VAF 32/100 reads (32%) | catalogued as COSV99179528; called by muse, mutect2, varscan2
- CATIP | c.921+1G>A p.X307_splice | Splice Site (SNP) | VAF 32/96 reads (33%) | catalogued as COSV56822453, COSV56822668; called by muse, mutect2, varscan2
- CCDC178 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.215); catalogued as COSV55763501; called by muse, mutect2, varscan2
- CCDC181 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63157206; called by muse, mutect2, varscan2
- CCDC9B | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101233462; called by muse, mutect2, varscan2
- CCNF | c.1433C>T p.T478I | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760280974; called by muse, mutect2
- CDHR2 | c.3751G>A p.D1251N | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.238); catalogued as rs556728793, COSV56143225; called by muse, mutect2, varscan2
- CDK12 | c.2651A>G p.Y884C | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs200264056; called by muse, varscan2
- CDKN1A | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 56/178 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs774390644, COSV55189534; called by muse, mutect2, varscan2
- CELSR2 | c.4181C>T p.S1394L | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs1557731321; called by muse, mutect2, varscan2
- CFAP57 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs543421429; called by muse, mutect2, varscan2
- CFAP74 | c.415C>T p.Q139* | Nonsense Mutation (SNP) | VAF 14/66 reads (21%) | catalogued as rs780541178; called by muse, mutect2, varscan2
- CFHR4 | c.410G>A p.G137E (on ENST00000367416 / NM_001201551.2; = p.G138E on NM_001201550.3) | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs779625743; called by muse, mutect2, varscan2
- CHPF | c.1423C>T p.Q475* | Nonsense Mutation (SNP) | VAF 10/43 reads (23%) | catalogued as COSV99705158; called by muse, mutect2, varscan2
- CLCNKA | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 45/200 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs868849719; called by muse, mutect2, varscan2
- CLEC1A | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100191377; called by muse, mutect2, varscan2
- CLEC3A | c.326G>A p.G109E (on ENST00000651443; = p.G100E on NM_005752.6) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55220771, COSV55222201; called by muse, mutect2, varscan2
- CLECL1 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV59932106; called by muse, mutect2, varscan2
- CLU | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.438); catalogued as COSV57065730; called by muse, mutect2, varscan2
- CNGA1 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs761061038, COSV62055811; called by muse, mutect2, varscan2
- CNGA3 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV55623557, COSV55626015; called by muse, mutect2, varscan2
- CNGB1 | c.2910G>A p.M970I | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as rs756942679, COSV51900934, COSV51902161; called by muse, mutect2, varscan2
- CNTN3 | c.2354G>A p.G785D | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55167677; called by muse, mutect2
- COL19A1 | c.1010G>A p.G337E | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59573948; called by muse, mutect2, varscan2
- COL4A4 | c.2755G>A p.E919K | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.82); catalogued as COSV104395242, COSV61636388; called by muse, mutect2, varscan2
- CPAMD8 | c.2104G>A p.E702K (on ENST00000651564; = p.E655K on NM_015692.5) | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.46); catalogued as rs1173529884, COSV52240736; called by muse, mutect2, varscan2
- CPLANE2 | c.431C>T p.S144F | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767538456, COSV100983286; called by muse, mutect2, varscan2
- CRACD | c.1426C>T p.R476C | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as rs1407907307, COSV51718305; called by muse, mutect2, varscan2
- CRB1 | c.2807G>A p.G936E | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66330947; called by muse, varscan2
- CREB3L4 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 79/344 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs760061506, COSV55133250; called by muse, mutect2, varscan2
- CSMD2 | c.7225G>A p.D2409N | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53975788; called by muse, mutect2
- CTTNBP2NL | c.1747C>T p.P583S | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99600315; called by muse, mutect2, varscan2
- CYB5R4 | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV100859641; called by muse, mutect2, varscan2
- CYFIP2 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV100556434; called by muse, mutect2, varscan2
- CYP11B1 | c.1165G>A p.D389N | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as rs200711326, COSV52828441; called by muse, varscan2
- CYP11B1 | c.1130C>T p.P377L | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs370757808; called by muse, varscan2
- CYP24A1 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.636); catalogued as COSV53772911; called by muse, mutect2, varscan2
- CYP2C9 | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53246164; called by muse, mutect2, varscan2
- CYP4V2 | c.1487G>A p.R496K | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as rs770843894; called by muse, mutect2, varscan2
- DAGLA | c.1253C>T p.P418L | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57195634; called by muse, mutect2
- DCAF11 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as rs144377321; called by muse, mutect2, varscan2
- DCC | c.3132G>A p.V1044= | Splice Region (SNP) | VAF 41/131 reads (31%) | catalogued as rs536843815, COSV104395482; called by muse, mutect2, varscan2
- DEFB125 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66703190, COSV66703511; called by muse, mutect2, varscan2
- DENND5A | c.3311A>G p.N1104S | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.7); PolyPhen benign (0.02); catalogued as rs757841417, COSV100064974; called by muse, varscan2
- DIO3 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.038); catalogued as COSV100832173, COSV63773017; called by muse, mutect2, varscan2
- DIPK1A | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV64790130; called by muse, mutect2, varscan2
- DNAH12 | c.5354G>A p.G1785E (on ENST00000351747; = p.G1804E on NM_001366028.2) | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV61055454; called by muse, mutect2, varscan2
- DOCK2 | c.3872G>A p.G1291E | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866879295, COSV56954699; called by muse, mutect2
- DOCK5 | c.2850C>T p.I950= | Splice Region (SNP) | VAF 26/82 reads (32%) | catalogued as rs780277079, COSV52395284, COSV99377355; called by muse, mutect2, varscan2
- DOK5 | c.290-1G>A p.X97_splice | Splice Site (SNP) | VAF 6/18 reads (33%) | catalogued as COSV52819784; called by mutect2, varscan2
- DPY19L2 | c.1744C>T p.R582C | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs199875016; called by muse, mutect2, varscan2
- DST | c.3422C>T p.S1141L (on ENST00000361203 / NM_001374722.1; = p.S815L on NM_001723.6) | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV99758385; called by muse, mutect2, varscan2
- DUOX2 | c.4046C>T p.S1349F | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as COSV66532279; called by muse, mutect2, varscan2
- DYNC2H1 | c.3643C>T p.R1215C | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs746768637; ClinVar: uncertain significance; called by mutect2, varscan2
- ELOA2 | c.854G>A p.G285E | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1213560157; called by mutect2, varscan2
- ENOX1 | c.1507G>A p.E503K | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.358); catalogued as COSV54905842; called by muse, mutect2, varscan2
- EPHA2 | c.2339C>T p.P780L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1440863246; called by muse, mutect2, varscan2
- ESCO2 | c.665C>T p.S222L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV104397214; called by mutect2, varscan2
- ETV5 | c.911-8C>T | Splice Region (SNP) | VAF 16/29 reads (55%) | catalogued as rs1560047249; called by muse, mutect2, varscan2
- EVPLL | c.893C>T p.S298F | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious, low confidence (0); catalogued as rs1206767171; called by muse, mutect2
- EYA4 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.06); catalogued as COSV62059291; called by muse, mutect2, varscan2
- F5 | c.6097G>A p.D2033N | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.802); catalogued as rs1343321355; called by muse, mutect2, varscan2
- FABP1 | c.66C>T p.I22= | Splice Region (SNP) | VAF 26/42 reads (62%) | catalogued as rs144343680; called by muse, mutect2, varscan2
- FABP2 | c.67G>A p.G23S | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs747477007; called by muse, mutect2
- FBXO27 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as rs370891116, COSV53072849; called by mutect2, varscan2
- FLG | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated (0.83); PolyPhen probably damaging (0.93); catalogued as rs745659334, COSV64246305; called by muse, mutect2, varscan2
- FOXA2 | c.1148C>T p.S383F (on ENST00000377115 / NM_153675.3; = p.S389F on NM_021784.5) | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745674979, COSV65796822; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1506G>A p.W502* | Nonsense Mutation (SNP) | VAF 18/64 reads (28%) | catalogued as COSV100437522; called by muse, mutect2, varscan2
- FRAS1 | c.9010G>A p.E3004K | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1470070058, COSV53627571; called by muse, mutect2, varscan2
- FREM2 | c.4479C>A p.Y1493* | Nonsense Mutation (SNP) | VAF 16/41 reads (39%) | catalogued as COSV54844157; called by mutect2, varscan2
- FRG2 | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); catalogued as rs1265619321, COSV101111584; called by mutect2, varscan2
- GALNT5 | c.1987G>A p.D663N | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as COSV52037695; called by muse, mutect2, varscan2
- GBP2 | c.1748C>T p.S583L | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as COSV100975412; called by muse, mutect2, varscan2
- GBP3 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs148562368; called by muse, mutect2, varscan2
- GJB5 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1316194621, COSV100258253; called by muse, varscan2
- GLYAT | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.091); catalogued as COSV53540433; called by muse, mutect2, varscan2
- GNGT2 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55930398; called by muse, mutect2
- GPR37 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs758470818, COSV58255922; called by muse, mutect2, varscan2
- GPR63 | c.1003C>T p.L335F | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs1414214299; called by muse, mutect2, varscan2
- GRIN2B | c.1280G>A p.G427E | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.337); catalogued as COSV74205182; called by muse, mutect2, varscan2
- HAPLN1 | c.76C>T p.H26Y | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57150254; called by muse, mutect2, varscan2
- HBA2 | c.374C>T p.S125F | Missense Mutation (SNP) | VAF 52/224 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV52406538; called by muse, mutect2, varscan2
- HCFC1 | c.2588C>T p.S863F | Missense Mutation (SNP) | VAF 100/158 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); catalogued as COSV60069835; called by muse, mutect2, varscan2
- HERC1 | c.727G>A p.G243S | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as COSV101496703; called by muse, varscan2
- HMGCL | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 58/301 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.09); catalogued as COSV52525489; called by muse, mutect2, varscan2
- HOXB13 | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV51707744; called by muse, mutect2, varscan2
- HPSE2 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.968); catalogued as rs767173222; called by muse, mutect2, varscan2
- HSPG2 | c.7684C>T p.P2562S | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.921); catalogued as rs755215244; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HTR3A | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.028); catalogued as rs145587443; called by muse, mutect2, varscan2
- IDE | c.2293C>T p.R765W | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.99); catalogued as rs760053435; called by muse, mutect2, varscan2
- IDH2 | c.1168G>A p.D390N | Missense Mutation (SNP) | VAF 63/158 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.009); catalogued as COSV99184180; called by muse, mutect2, varscan2
- IL19 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs769329582; called by muse, varscan2
- INVS | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1189239222, COSV52439946; called by muse, mutect2, varscan2
- IRF4 | c.1340C>T p.S447F | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as rs749474191, COSV101110980; called by muse, mutect2, varscan2
- JAK1 | c.2228C>T p.P743L | Missense Mutation (SNP) | VAF 77/125 reads (62%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as COSV100691754; called by muse, mutect2, varscan2
- JPH2 | c.822C>A p.D274E | Missense Mutation (SNP) | VAF 54/171 reads (32%) | SIFT tolerated (0.96); PolyPhen benign (0.092); catalogued as rs1385874818, COSV65904961; called by muse, mutect2, varscan2
- KATNAL2 | c.361C>T p.P121S (on ENST00000356157 / NM_001353899.1; = p.P49S on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs1232984882, COSV55299559; called by muse, mutect2, varscan2
- KCNC2 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV54369344; called by muse, mutect2, varscan2
- KIFC1 | c.1118C>T p.S373F | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs765880170, COSV65737434; called by muse, mutect2, varscan2
- KLHDC4 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs188149202; called by muse, mutect2, varscan2
- KRT13 | c.1270G>A p.G424R | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.956); catalogued as rs1268637975; called by muse, mutect2, varscan2
- KRT71 | c.1342C>T p.P448S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as COSV57292374; called by muse, varscan2
- KSR2 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as rs764042295, COSV100346525; called by muse, mutect2, varscan2
- LAMA1 | c.4454G>A p.G1485E | Missense Mutation (SNP) | VAF 58/206 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67533024; called by muse, mutect2, varscan2
- LCNL1 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.336); catalogued as COSV56401596; called by muse, mutect2
- LONRF2 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV66540201; called by muse, mutect2, varscan2
- LRP1B | c.6481C>T p.R2161* | Nonsense Mutation (SNP) | VAF 26/106 reads (25%) | catalogued as COSV67215667; called by muse, mutect2, varscan2
- LRP2 | c.6284G>A p.R2095Q | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs769929318, COSV55542779; called by muse, mutect2, varscan2
- LRP3 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs774083145, COSV53504445; called by muse, mutect2, varscan2
- LZTS1 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV56116269; called by muse, mutect2
- MAEL | c.1181C>T p.T394I | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.386); catalogued as rs1158687527; called by muse, mutect2
- MAGEL2 | c.2381C>T p.S794F | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV58567374; called by mutect2, varscan2
- MAP3K10 | c.2152C>T p.P718S | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as rs963649198, COSV53424821; called by muse, mutect2, varscan2
- MAP3K21 | c.2659C>T p.P887S | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs1022071835; called by muse, mutect2
- MAP3K4 | c.4096G>A p.G1366R | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100815616, COSV62329900; called by muse, mutect2, varscan2
- MED23 | c.2779-6C>T | Splice Region (SNP) | VAF 26/81 reads (32%) | catalogued as rs1399644326; called by muse, mutect2, varscan2
- MGAM | c.4597C>T p.Q1533* | Nonsense Mutation (SNP) | VAF 50/101 reads (50%) | catalogued as rs766526968, COSV72075858; called by muse, mutect2, varscan2
- MGAM2 | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1256118114; called by muse, mutect2, varscan2
- MIP | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752820201; called by muse, varscan2
- MLLT3 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs571802352; called by muse, mutect2, varscan2
- MROH9 | c.789G>A p.M263I | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.086); catalogued as COSV100882924; called by muse, mutect2, varscan2
- MTMR11 | c.1063C>T p.R355* (on ENST00000439741 / NM_001145862.2; = p.R283* on NM_181873.3) | Nonsense Mutation (SNP) | VAF 15/66 reads (23%) | catalogued as rs1191420920, COSV54964653; called by muse, mutect2, varscan2
- MUC16 | c.32426G>A p.R10809Q | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); catalogued as rs1349141481, COSV101200343; called by muse, mutect2, varscan2
- MUC16 | c.30292C>T p.P10098S | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.07); catalogued as rs1300905469; called by muse, mutect2, varscan2
- MUC16 | c.16828C>T p.R5610W | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.718); catalogued as rs753471783, COSV101199553, COSV67466155; called by muse, mutect2, varscan2
- MUC16 | c.9803C>T p.S3268L | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); catalogued as rs1324963810; called by muse, mutect2, varscan2
- MUC4 | c.12860C>T p.S4287F (on ENST00000463781 / NM_018406.7; = p.S51F on NM_004532.6) | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV57781409; called by muse, mutect2, varscan2
- MYH14 | c.3316G>A p.E1106K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1393112947; called by muse, mutect2
- MYH2 | c.5023G>A p.E1675K | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55437861; called by muse, mutect2, varscan2
- MYH2 | c.4781G>A p.R1594K | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.042); catalogued as COSV55442365, COSV55446942; called by muse, mutect2, varscan2
- MYH4 | c.3670G>A p.E1224K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55122787; called by muse, mutect2, varscan2
- MYH7 | c.2487G>A p.W829* | Nonsense Mutation (SNP) | VAF 17/70 reads (24%) | catalogued as COSV62520747; called by muse, mutect2, varscan2
- NAT16 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV55865466; called by muse, mutect2
- NEXMIF | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV50077394; called by muse, mutect2, varscan2
- NFASC | c.2987C>T p.T996I | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.139); catalogued as rs1200123263; called by muse, mutect2, varscan2
- NIPAL3 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV50237860; called by muse, mutect2, varscan2
- NLRP2 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs1165462336, COSV54756823; called by muse, mutect2, varscan2
- NLRP4 | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV100015586, COSV56709094; called by mutect2, varscan2
- NPHS2 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV62635285; called by muse, mutect2, varscan2
- NPY2R | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764371059, COSV61527463; called by muse, mutect2, varscan2
- NR3C2 | c.1955G>A p.R652Q | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60993950; called by muse, mutect2, varscan2
- NSD2 | c.1340C>T p.S447F | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as rs1306925576; called by muse, mutect2, varscan2
- NTRK3 | c.704G>A p.G235E | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58112376; called by muse, mutect2, varscan2
- OR10J1 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV71128713; called by muse, mutect2, varscan2
- OR10J5 | c.552G>A p.M184I | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.081); catalogued as COSV58386907; called by muse, mutect2, varscan2
- OR2B2 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); catalogued as COSV57580264; called by muse, mutect2, varscan2
- OR2L3 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.244); catalogued as COSV99057494; called by muse, mutect2, varscan2
- OR2T33 | c.133C>T p.L45F | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.048); catalogued as rs1203465264, COSV100531700; called by muse, mutect2, varscan2
- OR4C15 | c.530T>A p.V177E (on ENST00000314644; = p.V123E on NM_001001920.2) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV58955287; called by muse, varscan2
- OR4K1 | c.196C>T p.L66F | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53460010; called by muse, mutect2, varscan2
- OR4K14 | c.246G>A p.M82I | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); catalogued as rs1420560514; called by muse, mutect2, varscan2
- OR51I2 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.129); catalogued as COSV100413479; called by muse, mutect2
- OR52E8 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV66205250; called by muse, mutect2, varscan2
- OR5D16 | c.278C>T p.T93I | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as COSV65722993; called by muse, mutect2, varscan2
- OR5F1 | c.472G>A p.V158I | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.083); catalogued as rs760538244; called by muse, mutect2, varscan2
- OR5K3 | c.557G>A p.R186K | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.79); PolyPhen benign (0.029); catalogued as COSV67350216; called by mutect2, varscan2
- OR5M11 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs754849517, COSV73141718, COSV73141748; called by muse, varscan2
- OR6N1 | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs1485544575; called by muse, varscan2
- OR8G5 | c.475C>T p.H159Y | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.255); catalogued as rs748985450, COSV58383282; called by muse, mutect2, varscan2
- OTOG | c.6256C>T p.P2086S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs1380001909; called by muse, mutect2, varscan2
- P3H1 | c.1406C>T p.S469F | Missense Mutation (SNP) | VAF 65/217 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99355431; called by muse, mutect2, varscan2
- PARVG | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV63561803; called by muse, mutect2, varscan2
- PCDH15 | c.2290C>T p.R764C | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.849); catalogued as rs192813057, COSV57279849; ClinVar: uncertain significance; called by mutect2, varscan2
- PCDHA12 | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.503); catalogued as rs143847585, COSV56483117; called by muse, mutect2, varscan2
- PCDHB5 | c.2194C>T p.P732S | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.244); catalogued as COSV50648006; called by muse, mutect2, varscan2
- PCDHGB3 | c.497C>T p.S166L | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV53936919; called by muse, mutect2, varscan2
- PCK1 | c.1225C>T p.P409S | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV60127091; called by muse, mutect2, varscan2
- PDE6A | c.1756G>A p.D586N | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs191628052; called by muse, mutect2, varscan2
- PDGFRB | c.1687G>A p.E563K | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as rs1483057981, COSV55802825; called by muse, mutect2, varscan2
- PEX26 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 39/200 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs746675328, COSV61605101; called by muse, mutect2, varscan2
- PGGHG | c.2168C>T p.S723F | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV66887693; called by muse, mutect2, varscan2
- PID1 | c.325G>A p.G109S (on ENST00000354069 / NM_001330156.1; = p.G107S on NM_017933.5) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV62482370; called by muse, mutect2
- PIK3C2G | c.1079C>T p.S360F | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.865); catalogued as COSV56807940; called by muse, mutect2, varscan2
- PKD1L2 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as rs1405959722; called by muse, mutect2, varscan2
- PKDREJ | c.2758G>A p.D920N | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV104387581, COSV53546948; called by muse, mutect2, varscan2
- PKDREJ | c.1502G>A p.G501D | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs1290089544; called by muse, mutect2, varscan2
- PLA2G4A | c.1558G>A p.E520K | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as COSV66552504; called by muse, mutect2, varscan2
- PLAUR | c.331C>T p.R111* | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | catalogued as rs992988583; called by muse, mutect2
- PLCH1 | c.84G>A p.M28I (on ENST00000340059 / NM_001130960.2; = p.M40I on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV100397114, COSV100398559; called by muse, mutect2, varscan2
- PLEC | c.10058C>T p.A3353V (on ENST00000322810 / NM_201380.4; = p.A3243V on NM_000445.5) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as rs1554680911; called by muse, mutect2, varscan2
- PODN | c.1936G>A p.E646K (on ENST00000395871; = p.E598K on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV57016094; called by muse, mutect2, varscan2
- POLE | c.4139C>T p.S1380L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs762090058, COSV57674732; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POT1 | c.157A>G p.T53A | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV62933671; called by muse, mutect2, varscan2
- PPA1 | c.853C>T p.H285Y | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs149792334; called by muse, mutect2, varscan2
- PRAMEF11 | c.86C>T p.T29I | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs758413317; called by muse, mutect2, varscan2
- PREX2 | c.781C>T p.Q261* | Nonsense Mutation (SNP) | VAF 13/52 reads (25%) | catalogued as COSV99909048; called by muse, mutect2, varscan2
- PRKCQ | c.1387G>A p.G463R | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772062701, COSV54105592, COSV54114499; called by muse, mutect2, varscan2
- PRRC2C | c.4472C>T p.S1491L (on ENST00000367742; = p.S1489L on NM_015172.4) | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100144916; called by muse, mutect2, varscan2
- PTCH1 | c.4235C>T p.P1412L | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs766849993, COSV59471699, COSV59475536; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTER | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as rs374448904; called by muse, mutect2, varscan2
- PTPRR | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51733034; called by muse, mutect2, varscan2
- PURG | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.398); catalogued as rs1209271472, COSV53306582; called by muse, mutect2, varscan2
- RAET1E | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.268); catalogued as rs763046844; called by muse, mutect2, varscan2
- RAET1E | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.899); catalogued as rs768877474; called by muse, mutect2, varscan2
- RALGAPB | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV53442561; called by muse, mutect2, varscan2
- RESP18 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as COSV100345438; called by muse, mutect2, varscan2
- RGL4 | c.73G>A p.G25S | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); catalogued as rs763009412; called by muse, mutect2, varscan2
- RGS7 | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.393); catalogued as COSV58531038, COSV58536186; called by muse, mutect2, varscan2
- RHOH | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.042); catalogued as COSV67805418; called by muse, mutect2, varscan2
- RIPOR2 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as rs1358073490, COSV99430273; called by muse, mutect2, varscan2
- RIT2 | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56297770; called by muse, mutect2, varscan2
- RNF214 | c.1384C>T p.R462W | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs375077963; called by muse, mutect2
- RP1L1 | c.4702C>T p.L1568F | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1282133024, COSV101222972; called by muse, mutect2, varscan2
- RSL1D1 | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.221); catalogued as rs376755771; called by muse, mutect2, varscan2
- RTN4IP1 | c.797C>T p.S266F | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.206); catalogued as COSV64805358; called by muse, mutect2, varscan2
- SALL4 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 55/175 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.212); catalogued as CD031881; called by muse, mutect2, varscan2
- SCARF2 | c.1009G>A p.G337R | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746590819; called by muse, mutect2, varscan2
- SCN10A | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71861955; called by muse, mutect2, varscan2
- SCN2B | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV54051539; called by muse, mutect2, varscan2
- SCN4A | c.2915C>T p.P972L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.671); catalogued as COSV71126993; called by muse, mutect2, varscan2
- SELP | c.377G>A p.R126K | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs867399046; called by muse, mutect2, varscan2
- SEMA3C | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV99542890; called by muse, mutect2, varscan2
- SHC3 | c.776G>A p.G259E | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65438415, COSV65439153; called by muse, mutect2, varscan2
- SHISA9 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.06); catalogued as rs1436328307; called by muse, mutect2, varscan2
- SIPA1L2 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs760458046, COSV53396433; called by muse, mutect2, varscan2
- SKOR2 | c.1814C>T p.P605L | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); catalogued as COSV68550488; called by muse, mutect2
- SLC13A1 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 39/54 reads (72%) | SIFT tolerated (0.14); PolyPhen benign (0.099); catalogued as rs527709610, COSV52011432; called by muse, mutect2, varscan2
- SLC23A1 | c.1285G>A p.G429R | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100812130; called by muse, mutect2, varscan2
- SLC25A27 | c.781C>T p.R261* | Nonsense Mutation (SNP) | VAF 16/60 reads (27%) | catalogued as rs776429763, COSV100992926; called by muse, mutect2, varscan2
- SLC28A3 | c.1780G>A p.A594T | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1381161592; called by muse, mutect2, varscan2
- SLC39A4 | c.325G>A p.G109S (on ENST00000301305 / NM_001374839.1; = p.G84S on NM_017767.3) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.139); catalogued as rs781982424, COSV99433395; called by muse, mutect2, varscan2
- SLC44A3 | c.646C>T p.L216F (on ENST00000271227 / NM_001114106.3; = p.L168F on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.873); catalogued as rs374306426; called by muse, mutect2, varscan2
- SLC4A4 | c.1313G>A p.R438Q (on ENST00000264485 / NM_001098484.3; = p.R394Q on NM_003759.4) | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.233); catalogued as rs1169489768, COSV52615734; called by muse, mutect2, varscan2
- SLC6A12 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV62885170; called by muse, mutect2, varscan2
- SLC9B2 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs748510989; called by muse, mutect2, varscan2
- SLITRK2 | c.1823C>T p.S608F | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV59427757; called by muse, mutect2, varscan2
- SLITRK2 | c.2032G>A p.D678N | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT tolerated (0.39); PolyPhen benign (0.415); catalogued as COSV59428220; called by muse, mutect2, varscan2
- SLITRK6 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1310021586; called by muse, mutect2
- SORCS3 | c.1565G>A p.R522K | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV63813118; called by muse, mutect2, varscan2
- SOX17 | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.825); catalogued as COSV52027587; called by muse, mutect2, varscan2
- SPATA20 | c.2112C>T p.I704= (on ENST00000356488 / NM_001258372.1; = p.I720= on NM_022827.4) | Splice Region (SNP) | VAF 20/66 reads (30%) | catalogued as rs1011286631, COSV50066493; called by muse, mutect2, varscan2
- SPATA31A3 | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.947); catalogued as rs1259376550; called by muse, mutect2, varscan2
- SPOCK3 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.091); catalogued as rs1422436706, COSV62718113; called by muse, mutect2
- SPTBN1 | c.7025C>T p.P2342L | Missense Mutation (SNP) | VAF 127/439 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0.035); catalogued as COSV100777228; called by muse, mutect2, varscan2
- SRPX2 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 39/51 reads (76%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100884055; called by muse, mutect2, varscan2
- SRRM4 | c.1216C>T p.R406* | Nonsense Mutation (SNP) | VAF 25/83 reads (30%) | catalogued as rs373815603, COSV57414549; called by muse, mutect2, varscan2
- STK32A | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs375612505; called by muse, mutect2, varscan2
- STRN | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.334); catalogued as COSV99814821; called by muse, mutect2, varscan2
- SYDE2 | c.3488G>A p.R1163Q | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as rs775631372, COSV58323150; called by mutect2, varscan2
- SYNPR | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.995); catalogued as COSV55723636; called by muse, mutect2, varscan2
- SYPL2 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.659); catalogued as rs192895878, COSV63994891; called by muse, mutect2, varscan2
- TAF1L | c.2267G>A p.G756D | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1367985899; called by muse, varscan2
- TAF1L | c.2120G>A p.G707E | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as COSV54259613; called by muse, varscan2
- TBX1 | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 52/197 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.306); catalogued as rs1271766131; called by muse, mutect2, varscan2
- TEX15 | c.3191C>T p.S1064L (on ENST00000256246; = p.S1447L on NM_001350162.2) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746972978, COSV56353783; called by muse, mutect2
- TGM2 | c.1939G>A p.E647K | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV63932420; called by muse, mutect2
- THSD7A | c.1522C>T p.P508S | Missense Mutation (SNP) | VAF 58/184 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.303); catalogued as COSV70263553; called by muse, mutect2, varscan2
- TINAG | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as COSV99449822; called by muse, mutect2, varscan2
- TJP1 | c.4703C>T p.P1568L | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.055); catalogued as COSV62042985; called by muse, mutect2, varscan2
- TMEM125 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs866793997, COSV71326927; called by muse, mutect2, varscan2
- TMEM87A | c.143C>T p.S48L | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1566945854; called by muse, mutect2
- TMPRSS11E | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV100542393; called by muse, mutect2, varscan2
- TMPRSS4 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as rs1480546611, COSV71108394; called by muse, mutect2, varscan2
- TNR | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54905885; called by muse, varscan2
- TOP3B | c.437C>T p.T146I | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV64118984; called by muse, mutect2, varscan2
- TOPAZ1 | c.3232G>A p.E1078K | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV59066092; called by mutect2, varscan2
- TPK1 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.704); catalogued as rs368467309; called by muse, mutect2, varscan2
- TRBV7-1 | c.151C>A p.L51I | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.775); catalogued as rs1336475809; called by muse, mutect2, varscan2
- TRIM17 | c.430T>C p.L144= | Splice Region (SNP) | VAF 23/86 reads (27%) | catalogued as rs776945072; called by muse, mutect2, varscan2
- TRIM49B | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.179); catalogued as COSV60320902; called by muse, varscan2
- TRIM64B | c.236A>C p.Q79P | Missense Mutation (SNP) | VAF 36/211 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV99052243; called by muse, mutect2, varscan2
- TRPM2 | c.4049C>T p.P1350L | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.042); catalogued as COSV100308583; called by muse, mutect2, varscan2
- TRPM4 | c.270C>T p.F90= | Splice Region (SNP) | VAF 39/112 reads (35%) | catalogued as COSV53268719; called by muse, varscan2
- TSPAN32 | c.183C>T p.A61= | Splice Region (SNP) | VAF 18/67 reads (27%) | catalogued as rs1490453729; called by muse, mutect2, varscan2
- TUBB8B | c.1078G>A p.G360R | Missense Mutation (SNP) | VAF 80/160 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs773538325; called by muse, varscan2
- ULK1 | c.1846C>T p.P616S | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs763744221; called by muse, mutect2, varscan2
- ULK1 | c.1847C>T p.P616L | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs577850298; called by muse, mutect2, varscan2
- UPF1 | c.2321C>T p.S774F (on ENST00000599848 / NM_001297549.2; = p.S763F on NM_002911.4) | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53196731; called by muse, mutect2, varscan2
- USH2A | c.5996C>T p.P1999L | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV56381219; called by muse, mutect2, varscan2
- USH2A | c.1462C>T p.H488Y | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV56393899; called by muse, mutect2, varscan2
- USH2A | c.7T>C p.C3R | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs1007387309; called by muse, mutect2, varscan2
- USP17L7 | c.1311G>A p.W437* | Nonsense Mutation (SNP) | VAF 34/234 reads (15%) | catalogued as rs1285602004; called by muse, mutect2, varscan2
- USP17L7 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0.411); catalogued as rs746337329, COSV61556189; called by muse, mutect2
- VRTN | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as rs1417079037; called by muse, mutect2, varscan2
- VWA3B | c.1876G>A p.E626K | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101346118; called by muse, varscan2
- VWA8 | c.2725C>T p.P909S | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV55705277; called by muse, mutect2, varscan2
- VWF | c.2432C>T p.P811L | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1478975030, COSV54633323; called by muse, mutect2
- WASF1 | c.188C>T p.S63F | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55620449; called by muse, mutect2, varscan2
- ZEB2 | c.1351C>T p.P451S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.298); catalogued as COSV57962780; called by muse, mutect2, varscan2
- ZFYVE19 | c.710C>T p.P237L (on ENST00000355341 / NM_001077268.2; = p.P227L on NM_032850.5) | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.197); catalogued as rs868816958; called by muse, mutect2, varscan2
- ZMIZ2 | c.2326C>T p.P776S | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV54809155; called by muse, mutect2, varscan2
- ZNF135 | c.1841C>T p.S614F (on ENST00000313434 / NM_001289401.2; = p.S626F on NM_003436.4) | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.182); catalogued as COSV57881218; called by muse, mutect2, varscan2
- ZNF679 | c.469C>T p.Q157* | Nonsense Mutation (SNP) | VAF 19/50 reads (38%) | catalogued as rs1172905173, COSV55382405; called by muse, mutect2, varscan2
- ZNF728 | c.1037G>A p.G346D | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV74099080; called by muse, mutect2, varscan2
- ZNF735 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.09); catalogued as COSV70035845; called by muse, mutect2, varscan2
- ZNF845 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.017); catalogued as COSV72004328; called by muse, mutect2, varscan2
- AADAT | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ABCB11 | c.2065G>A p.D689N | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ABCB5 | c.2780C>T p.A927V (on ENST00000404938 / NM_001163941.2; = p.A482V on NM_178559.6) | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ABCC10 | c.2720C>T p.S907F (on ENST00000372530 / NM_001198934.2; = p.S879F on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- AC004593.2 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 58/105 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AC093791.1 | n.466G>A | Splice Region (SNP) | VAF 16/44 reads (36%) | called by muse, mutect2, varscan2
- ACTN2 | c.2171G>A p.W724* | Nonsense Mutation (SNP) | VAF 45/161 reads (28%) | called by muse, mutect2, varscan2
- ADAM21 | c.650A>G p.N217S | Missense Mutation (SNP) | VAF 47/73 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ADAMTS13 | c.112C>T p.L38F | Missense Mutation (SNP) | VAF 80/223 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADGRG4 | c.6965C>T p.S2322F | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AFF3 | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AFTPH | c.2594C>T p.S865L (on ENST00000238855 / NM_203437.3; = p.S837L on NM_017657.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- AGO1 | c.2161C>T p.R721* | Nonsense Mutation (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- AHDC1 | c.2690C>T p.P897L | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- AHDC1 | c.2689C>T p.P897S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- ALDH1A1 | c.1424G>A p.G475E | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALMS1 | c.9353G>A p.G3118E | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ALPK1 | c.700-1G>A p.X234_splice | Splice Site (SNP) | VAF 24/59 reads (41%) | called by muse, mutect2, varscan2
- AMHR2 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- AMPD1 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ANK3 | c.11486G>A p.G3829E | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANK3 | c.6500C>A p.T2167N | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ANKRD18B | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKRD30B | c.1831C>T p.P611S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.81); PolyPhen benign (0.001); called by muse, varscan2
- ANKRD34C | c.637C>T p.Q213* | Nonsense Mutation (SNP) | VAF 23/49 reads (47%) | called by muse, mutect2, varscan2
- ANKS1B | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ANKS6 | c.1676C>T p.P559L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ANKS6 | c.1675C>T p.P559S | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- AP002512.3 | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- APBA2 | c.1966C>T p.P656S | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ARAP2 | c.3505G>A p.D1169N | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGAP35 | c.4164del p.N1389Ifs*3 | Frame Shift Del (DEL) | VAF 8/25 reads (32%) | called by mutect2, pindel, varscan2
- ARL14EP | c.625T>G p.C209G | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ARMC5 | c.517C>T p.R173* | Nonsense Mutation (SNP) | VAF 42/168 reads (25%) | called by muse, mutect2, varscan2
- ARRDC3 | c.1229C>T p.S410F | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.047); called by muse, mutect2
- ARSF | c.1085G>A p.W362* | Nonsense Mutation (SNP) | VAF 10/18 reads (56%) | called by mutect2, varscan2
- ASTN1 | c.3601A>C p.S1201R | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- ATG4B | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP1A4 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.04); called by muse, mutect2
- B4GALNT2 | c.172C>T p.H58Y | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- B4GALNT4 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BORCS5 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 60/182 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- C18orf63 | c.1703G>A p.G568E | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- C1QTNF4 | c.964G>A p.G322S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2
- C4BPB | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.81); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CA10 | c.263A>C p.N88T | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- CA14 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- CACNA2D1 | c.1751G>A p.G584E (on ENST00000356253 / NM_001366867.1; = p.G565E on NM_000722.4) | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, varscan2
- CAPN9 | c.1609G>A p.V537M | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); called by muse, mutect2
- CBX4 | c.1469C>T p.S490F | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCBE1 | c.235A>G p.K79E | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by mutect2, varscan2
- CCDC158 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CCDC168 | c.19208C>T p.S6403F | Missense Mutation (SNP) | VAF 67/171 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- CCDC178 | c.1757C>T p.P586L | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- CCDC68 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- CCL4 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CD3G | c.79+5G>A | Splice Region (SNP) | VAF 27/132 reads (20%) | called by muse, mutect2, varscan2
- CD44 | c.1901G>A p.G634E | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CD46 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CDC42BPA | c.5090C>T p.S1697F (on ENST00000334218 / NM_001366019.2; = p.S1684F on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CDH7 | c.2206G>A p.E736K | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CDRT1 | c.1870C>T p.L624F | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- CFAP47 | c.7061G>A p.G2354E | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CFAP57 | c.3550G>A p.D1184N (on ENST00000372492 / NM_001378189.1; = p.D1217N on NM_001195831.3) | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CFH | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.023); called by muse, varscan2
- CIPC | c.221G>A p.R74K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CLDN12 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- CLDN18 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- COL11A1 | c.2323G>A p.G775R | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL22A1 | c.3083G>A p.G1028E | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL6A6 | c.4003G>A p.G1335R | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- CSF3 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CTAGE1 | c.1673C>T p.P558L | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- CYP4F12 | c.1354G>A p.G452R | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- DBH | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DENND1B | c.1690G>A p.E564K | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- DENND6A | c.1391G>T p.S464I | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.391); called by mutect2, varscan2
- DERPC | c.1076C>T p.A359V | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DIP2B | c.1759T>A p.S587T | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.217); called by mutect2, varscan2
- DMBT1 | c.2504C>T p.S835F | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- DNAH11 | c.8203A>T p.I2735L | Missense Mutation (SNP) | VAF 49/88 reads (56%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DNAH2 | c.9806C>T p.S3269F | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- DNAJC6 | c.2553G>A p.W851* | Nonsense Mutation (SNP) | VAF 34/94 reads (36%) | called by muse, mutect2, varscan2
- DOK5 | c.753T>G p.S251R | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.766); called by muse, varscan2
- DPP6 | c.1489G>A p.G497R (on ENST00000377770 / NM_001364500.2; = p.G435R on NM_001936.5) | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- DPYD | c.1585G>A p.D529N | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DRD1 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DSCAML1 | c.1060T>A p.C354S (on ENST00000321322; = p.C294S on NM_020693.4) | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- DSG2 | c.1564G>A p.G522R | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- DST | c.6514G>A p.E2172K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DYNC2I1 | c.1372C>T p.P458S | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ECE1 | c.2204C>T p.S735F | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- ECM1 | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 54/186 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, varscan2
- EDRF1 | c.1108C>T p.H370Y (on ENST00000356792 / NM_001202438.2; = p.H336Y on NM_015608.2) | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- EFTUD2 | c.1963-5C>T | Splice Region (SNP) | VAF 29/86 reads (34%) | called by muse, mutect2, varscan2
- ENDOU | c.50G>A p.W17* | Nonsense Mutation (SNP) | VAF 40/94 reads (43%) | called by muse, mutect2, varscan2
- ENPEP | c.1633C>T p.P545S | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ENPP1 | c.2363G>A p.R788K | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.06); called by muse, varscan2
- EPB41L3 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPHB6 | c.879G>A p.W293* | Nonsense Mutation (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2
- ERBB3 | c.873C>T p.P291= | Splice Region (SNP) | VAF 19/81 reads (23%) | called by muse, mutect2, varscan2
- ERI3 | c.763C>T p.P255S | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ERICH6B | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- F2 | c.1862G>A p.G621E | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- F5 | c.2371C>T p.L791F | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM210B | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM50B | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- FAM71A | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by mutect2, varscan2
- FAM83H | c.3454G>A p.E1152K | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FAT4 | c.4601C>T p.A1534V | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- FLG | c.11662C>A p.H3888N | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- FMN1 | c.3289-1G>A p.X1097_splice (on ENST00000616417 / NM_001277313.2; = p.X874_splice on NM_001103184.4) | Splice Site (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- FMN1 | c.1703C>T p.A568V | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.335); called by muse, varscan2
- FNIP1 | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by mutect2, varscan2
- FRMPD1 | c.3464G>A p.G1155D | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- FUT5 | c.548G>A p.G183D | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GALNT13 | c.165A>C p.E55D | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GCM2 | c.463G>A p.G155R | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- GLI2 | c.2044G>A p.D682N (on ENST00000361492 / NM_001374353.1; = p.D699N on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.486); called by mutect2, varscan2
- GP2 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- GPC3 | c.339G>A p.E113= | Splice Region (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2, varscan2
- HCN4 | c.3398G>A p.G1133E | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2
- HERC5 | c.645G>A p.W215* | Nonsense Mutation (SNP) | VAF 19/35 reads (54%) | called by muse, mutect2, varscan2
- HERC6 | c.1871C>T p.P624L | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- HFM1 | c.3763C>T p.Q1255* | Nonsense Mutation (SNP) | VAF 9/43 reads (21%) | called by muse, mutect2, varscan2
- HK3 | c.1960del p.E654Sfs*2 | Frame Shift Del (DEL) | VAF 3/23 reads (13%) | called by pindel, varscan2
- HMCN1 | c.13198G>A p.G4400S | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.796); called by muse, mutect2
- HOXC4 | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- HRNR | c.2594C>T p.S865F | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- HSD11B1 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- HSPA1L | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- HTR1D | c.989C>T p.S330F | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- IL13 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- IL1RAPL1 | c.1016G>A p.G339E | Missense Mutation (SNP) | VAF 43/65 reads (66%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.851); called by muse, varscan2
- ILDR2 | c.1774C>T p.P592S | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- INSC | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- IRAK4 | c.916C>T p.H306Y | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- IRS2 | c.3649G>A p.G1217S | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2
- IRX5 | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- ITCH | c.1419-2_1436del p.X473_splice (on ENST00000262650 / NM_001257137.3; = p.X432_splice on NM_031483.7 and 1 other RefSeq transcript) | Splice Site (DEL) | VAF 12/64 reads (19%) | called by mutect2, pindel*
- JAK1 | c.2227C>T p.P743S | Missense Mutation (SNP) | VAF 80/127 reads (63%) | SIFT tolerated (0.85); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- KANSL1 | c.11T>C p.M4T | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- KCNA2 | c.1076C>T p.P359L | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KCNG2 | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.676); called by muse, mutect2
- KCNH8 | c.1177G>A p.G393S | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- KIF21A | c.935G>A p.G312E | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIFC2 | c.2099C>T p.T700I | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- KIFC3 | c.2471C>T p.P824L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.025); called by muse, mutect2
- KLHL17 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KRT6A | c.1016C>G p.A339G | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- KRT85 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KRTAP13-3 | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KSR1 | c.2356G>A p.G786R (on ENST00000644974 / NM_001367810.1; = p.G671R on NM_014238.2) | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- LAMA1 | c.3322C>T p.L1108F | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- LAMC3 | c.4401G>A p.M1467I | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- LCE2C | c.158G>A p.G53E | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LCNL1 | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2
- LMBR1L | c.1217T>C p.L406P | Missense Mutation (SNP) | VAF 61/182 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- LMO7 | c.1391C>T p.S464F (on ENST00000357063; = p.S194F on NM_015842.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- LPCAT2 | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- LRRC6 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- LRRC9 | c.658C>T p.H220Y | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- LRRN4 | c.2172C>A p.Y724* | Nonsense Mutation (SNP) | VAF 50/149 reads (34%) | called by muse, mutect2, varscan2
- LY9 | c.608G>A p.G203E | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT tolerated (0.98); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- MAGI3 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- MAP1A | c.7894C>T p.P2632S | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MARCHF4 | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- MEGF10 | c.2060C>T p.S687F | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- MEP1B | c.1643G>A p.G548E | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MGAM | c.5086G>A p.E1696K | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MGRN1 | c.1620C>T p.A540= | Splice Region (SNP) | VAF 24/88 reads (27%) | called by mutect2, varscan2
- MGRN1 | c.1621C>T p.L541= | Splice Region (SNP) | VAF 26/97 reads (27%) | called by muse, mutect2, varscan2
- MIP | c.580C>T p.L194F | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.575); called by muse, varscan2
- MPI | c.1108C>T p.L370F | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- MUC16 | c.1613A>T p.E538V | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- MUC3A | c.7762A>G p.T2588A | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- MUC6 | c.1289C>T p.P430L | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- MYH14 | c.5845C>T p.P1949S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); called by muse, mutect2
- MYH2 | c.2158C>T p.L720F | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- MYH3 | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- MYOM2 | c.1461A>G p.Q487= | Splice Region (SNP) | VAF 15/40 reads (38%) | called by muse, varscan2
- MYT1 | c.2197G>A p.D733N | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- NCAN | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 8/11 reads (73%) | called by muse, mutect2, varscan2
- NEFM | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- NID1 | c.2444C>T p.A815V | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLRP2 | c.2041G>A p.D681N | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- NOC2L | c.1630C>T p.P544S | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- NPIPB15 | c.928C>T p.P310S | Missense Mutation (SNP) | VAF 31/259 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- NPTX1 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NSF | c.1894A>C p.K632Q | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- NUP43 | c.121-4A>C | Splice Region (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2, varscan2
- OAZ3 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 68/271 reads (25%) | SIFT tolerated (0.73); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OPN3 | c.599C>T p.S200F | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- OR2F2 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.8); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR51I2 | c.251C>T p.T84I | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (1); PolyPhen probably damaging (0.991); called by muse, mutect2
- OR6J1 | c.902G>A p.R301K | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.76); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OTOF | c.1863G>A p.M621I | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- PCARE | c.2605G>A p.E869K | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- PCDH10 | c.3002C>T p.S1001F | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PCDHA12 | c.532T>C p.F178L | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- PDE2A | c.2606C>T p.P869L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PDE3B | c.1318A>G p.R440G | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PDE3B | c.2617C>T p.H873Y | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PDE6C | c.1414-1G>C p.X472_splice | Splice Site (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- PGAP4 | c.893C>T p.S298F | Missense Mutation (SNP) | VAF 64/167 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- PHF12 | c.1469C>T p.S490F | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- PHLPP2 | c.2280C>T p.S760= | Splice Region (SNP) | VAF 34/70 reads (49%) | called by muse, mutect2, varscan2
- PIK3R6 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PLA2G4C | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- PLEKHA2 | c.677C>T p.T226I | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- PODXL | c.952C>T p.P318S (on ENST00000378555 / NM_001018111.3; = p.P286S on NM_005397.4) | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POM121L2 | c.1417C>T p.P473S | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- PPFIA2 | c.3362G>A p.G1121E | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPM1H | c.1381C>T p.P461S | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- PPP1R11 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PPP1R26 | c.1628C>T p.A543V | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- PPRC1 | c.3623C>T p.P1208L | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2
- PRKCE | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 63/179 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- PRPF38A | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0.017); called by muse, mutect2
- PRPF4B | c.2771A>T p.D924V | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRR30 | c.658G>A p.G220R | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRK | c.1061A>T p.D354V | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RABGGTA | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- RARG | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.077); called by muse, varscan2
- RASSF3 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 39/199 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- REG3G | c.223A>T p.K75* | Nonsense Mutation (SNP) | VAF 16/49 reads (33%) | called by muse, mutect2, varscan2
- RET | c.2137-1G>A p.X713_splice | Splice Site (SNP) | VAF 17/77 reads (22%) | called by muse, mutect2, varscan2
- RETREG2 | c.1391C>T p.P464L | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- RGS6 | c.69G>A p.M23I | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RIMS1 | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RP1 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RP1 | c.3961C>T p.H1321Y | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RPS24 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- RPTOR | c.3977C>T p.S1326F | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- RSPH6A | c.2101G>A p.E701K | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- RYR3 | c.2950G>A p.D984N | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SCN4A | c.5182G>A p.E1728K | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- SCNN1B | c.1715C>T p.A572V | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- SELL | c.323G>A p.G108E (on ENST00000650983; = p.G95E on NM_000655.5) | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- SELL | c.322G>A p.G108R (on ENST00000650983; = p.G95R on NM_000655.5) | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- SFSWAP | c.1013C>T p.S338F | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- SIGLEC9 | c.1328G>A p.R443K | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- SLC12A8 | c.1532C>T p.S511F | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- SLC17A3 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC17A7 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SLC18A1 | c.1535C>T p.P512L | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC25A24 | c.955G>A p.G319S | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT tolerated (0.4); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SLC4A4 | c.3082G>A p.D1028N (on ENST00000264485 / NM_001098484.3; = p.D984N on NM_003759.4) | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- SLC6A13 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.48); PolyPhen benign (0.049); called by muse, mutect2
- SLC7A11 | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SNTG1 | c.220-1G>A p.X74_splice | Splice Site (SNP) | VAF 7/16 reads (44%) | called by muse, mutect2, varscan2
- SNX13 | c.2107G>T p.V703F | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- SP4 | c.1834C>T p.Q612* | Nonsense Mutation (SNP) | VAF 36/153 reads (24%) | called by muse, mutect2, varscan2
- SPANXB1 | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 35/261 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SPINK5 | c.81+8C>T | Splice Region (SNP) | VAF 7/89 reads (8%) | called by muse, mutect2
- SPON1 | c.944C>T p.S315F | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SRRM1 | c.1493C>T p.S498F | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ST8SIA3 | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SYCP2L | c.2194G>A p.E732K | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TACC2 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- TAF1C | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 65/157 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TAF1C | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 64/155 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- TBCEL | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- TBX18 | c.175G>A p.G59S | Missense Mutation (SNP) | VAF 62/169 reads (37%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- TCTE1 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- TDRD15 | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- TDRD6 | c.1033C>T p.H345Y | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- TERT | c.2605G>A p.D869N | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TIAM1 | c.1739T>G p.M580R | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- TLN1 | c.4768C>T p.P1590S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNFSF13B | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- TNNI3 | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- TNR | c.3191C>T p.P1064L | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRAF3 | c.724_726+16del p.X242_splice | Splice Site (DEL) | VAF 42/192 reads (22%) | called by mutect2, pindel
- TRAPPC12 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- TRAV38-1 | c.168G>A p.W56* | Nonsense Mutation (SNP) | VAF 14/56 reads (25%) | called by muse, mutect2
- TRIM64B | c.699G>A p.W233* | Nonsense Mutation (SNP) | VAF 17/88 reads (19%) | called by muse, mutect2, varscan2
- TRPM1 | c.2733G>A p.M911I | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTC26 | c.805G>A p.G269R | Missense Mutation (SNP) | VAF 35/45 reads (78%) | SIFT deleterious (0.02); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TTK | c.1664T>G p.V555G | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TULP2 | c.323G>A p.G108D | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TYR | c.992C>T p.S331F | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- UBAP2L | c.1280C>T p.S427F | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- UGT1A7 | c.239C>T p.S80L | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.02); called by muse, mutect2
- UGT2A2 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.87); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- USP25 | c.2317C>T p.P773S | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- WBP2 | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- XAB2 | c.503G>A p.G168D | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- XKR3 | c.1229C>T p.P410L | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- XKR6 | c.1724G>A p.G575E | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- XYLT1 | c.1669C>T p.R557C | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- YOD1 | c.920G>A p.R307K | Missense Mutation (SNP) | VAF 53/248 reads (21%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZBED9 | c.1901G>A p.G634E | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZBTB21 | c.899del p.G300Vfs*14 | Frame Shift Del (DEL) | VAF 9/41 reads (22%) | called by mutect2, pindel, varscan2
- ZEB2 | c.605G>A p.G202E | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- ZFYVE28 | c.1364A>G p.E455G | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- ZNF185 | c.1333C>T p.P445S | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZNF441 | c.1393C>T p.H465Y | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF485 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ZNF532 | c.821T>C p.I274T | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- ZNF578 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZNF676 | c.1646C>T p.S549F (on ENST00000650058; = p.S517F on NM_001001411.3) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ZNF676 | c.1030G>A p.E344K (on ENST00000650058; = p.E312K on NM_001001411.3) | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.664); called by muse, varscan2
- ZNF814 | c.1237T>A p.C413S | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- ZNF84 | c.1744C>T p.Q582* | Nonsense Mutation (SNP) | VAF 29/109 reads (27%) | called by muse, mutect2, varscan2
- ZNF875 | c.1918T>C p.C640R | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNRF3 | c.689C>T p.S230F (on ENST00000544604 / NM_001206998.2; = p.S130F on NM_032173.3) | Missense Mutation (SNP) | VAF 44/209 reads (21%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- ABCA7 | c.3018C>T p.D1006= | Silent (SNP) | VAF 26/98 reads (27%) | called by muse, mutect2, varscan2
- ABCA8 | c.3060C>G p.L1020= | Silent (SNP) | VAF 15/44 reads (34%) | called by muse, mutect2, varscan2
- ABCC2 | c.1036C>T p.L346= | Silent (SNP) | VAF 48/145 reads (33%) | called by muse, mutect2, varscan2
- ABCC9 | c.2556G>A p.Q852= | Silent (SNP) | VAF 30/73 reads (41%) | called by muse, mutect2, varscan2
- ABLIM2 | c.1782C>T p.D594= (on ENST00000341937 / NM_001130084.2; = p.D504= on NM_032432.5) | Silent (SNP) | VAF 37/143 reads (26%) | catalogued as COSV56404552; called by muse, mutect2, varscan2
- AC099489.1 | c.3276C>T p.F1092= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV60862940; called by muse, mutect2, varscan2
- ACTRT3 | c.690C>T p.P230= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as COSV57754143; called by muse, mutect2, varscan2
- ADA2 | c.552G>A p.R184= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as COSV99375967; called by muse, mutect2
- ADAM29 | c.768C>T p.L256= | Silent (SNP) | VAF 13/29 reads (45%) | called by muse, mutect2
- ADCY7 | c.894G>A p.K298= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as rs1401360128; called by muse, mutect2
- ADGRB2 | c.939G>A p.E313= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as rs1489480941; called by muse, mutect2, varscan2
- ADGRL2 | c.2062C>T p.L688= (on ENST00000370717 / NM_001366005.1; = p.L675= on NM_012302.4) | Silent (SNP) | VAF 31/143 reads (22%) | called by muse, mutect2, varscan2
- AHNAK2 | c.13623C>T p.G4541= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs1465984622; called by muse, mutect2, varscan2
- AHNAK2 | c.12555C>T p.S4185= | Silent (SNP) | VAF 28/126 reads (22%) | catalogued as rs574126026; called by muse, varscan2
- AHNAK2 | c.4593C>T p.S1531= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV100317813; called by muse, mutect2, varscan2
- AHNAK2 | c.3603C>T p.S1201= | Silent (SNP) | VAF 12/31 reads (39%) | called by muse, mutect2, varscan2
- AHNAK2 | c.825C>T p.P275= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV60908575; called by muse, mutect2
- AKAP3 | c.396G>A p.T132= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs751629850, COSV99961733; called by muse, mutect2, varscan2
- AKR1B10 | c.363C>T p.D121= | Silent (SNP) | VAF 50/81 reads (62%) | catalogued as rs199767638; called by muse, mutect2, varscan2
- ALCAM | c.504C>T p.I168= | Silent (SNP) | VAF 21/38 reads (55%) | called by muse, mutect2, varscan2
- ALDH1A2 | c.462T>G p.A154= | Silent (SNP) | VAF 7/37 reads (19%) | called by muse, varscan2
- ALK | c.2301G>A p.K767= | Silent (SNP) | VAF 28/34 reads (82%) | called by muse, mutect2, varscan2
- AMPD3 | c.747C>T p.P249= (on ENST00000396553 / NM_001025389.2; = p.P258= on NM_000480.3) | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs771609974, COSV67330201; called by muse, mutect2, varscan2
- AMPH | c.219C>T p.A73= | Silent (SNP) | VAF 16/66 reads (24%) | called by muse, mutect2, varscan2
- ANKRD24 | c.2736C>T p.S912= | Silent (SNP) | VAF 13/38 reads (34%) | called by muse, mutect2, varscan2
- ANO4 | c.2064G>A p.R688= (on ENST00000392977 / NM_001286615.2; = p.R653= on NM_178826.4) | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs1403569410, COSV100153464; called by muse, mutect2, varscan2
- AOX1 | c.1987C>T p.L663= | Silent (SNP) | VAF 18/57 reads (32%) | called by muse, mutect2, varscan2
- AP2A2 | c.1257C>T p.I419= | Silent (SNP) | VAF 24/54 reads (44%) | called by muse, mutect2, varscan2
- APCDD1 | c.408C>T p.I136= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs1428198099, COSV62372531; called by muse, mutect2, varscan2
- ARHGEF11 | c.2568C>T p.F856= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs771941595; called by muse, mutect2
- ARHGEF38 | c.1833G>A p.V611= | Silent (SNP) | VAF 9/31 reads (29%) | called by muse, mutect2, varscan2
- ASCL2 | c.210C>T p.F70= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs749858000; called by muse, mutect2, varscan2
- BEST4 | c.754C>T p.L252= | Silent (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2, varscan2
- BEST4 | c.753C>T p.S251= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs766763709; called by muse, mutect2, varscan2
- BICD1 | c.867C>T p.I289= | Silent (SNP) | VAF 21/101 reads (21%) | called by muse, mutect2, varscan2
- BMP5 | c.42C>T p.F14= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as rs986883581; called by muse, mutect2, varscan2
- C14orf180 | c.417C>T p.L139= | Silent (SNP) | VAF 17/76 reads (22%) | called by muse, mutect2, varscan2
- C1orf167 | c.2682C>T p.F894= | Silent (SNP) | VAF 4/21 reads (19%) | called by muse, mutect2, varscan2
- C2orf78 | c.1365G>A p.P455= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as rs763384336, COSV68516321, COSV68516677; called by mutect2, varscan2
- C4orf54 | c.2577G>A p.E859= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as rs919343920; called by muse, mutect2, varscan2
- C5orf34 | c.552A>G p.G184= | Silent (SNP) | VAF 25/64 reads (39%) | called by muse, mutect2, varscan2
- C7orf57 | c.594C>T p.S198= | Silent (SNP) | VAF 17/67 reads (25%) | called by muse, mutect2, varscan2
- CACNA1A | c.2046G>A p.G682= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs750324942; called by muse, mutect2, varscan2
- CACNA1C | c.2154T>C p.A718= | Silent (SNP) | VAF 19/75 reads (25%) | called by muse, varscan2
- CACNA1I | c.1308G>A p.E436= | Silent (SNP) | VAF 14/82 reads (17%) | called by muse, mutect2, varscan2
- CACNG5 | c.120G>A p.V40= | Silent (SNP) | VAF 16/50 reads (32%) | called by muse, mutect2, varscan2
- CADM1 | c.960G>A p.G320= | Silent (SNP) | VAF 25/83 reads (30%) | called by muse, mutect2, varscan2
- CAMK1G | c.891G>A p.K297= | Silent (SNP) | VAF 23/110 reads (21%) | catalogued as COSV50520297; called by muse, mutect2, varscan2
- CAPN10 | c.1995C>T p.S665= | Silent (SNP) | VAF 27/87 reads (31%) | catalogued as rs755174264; called by muse, mutect2, varscan2
- CAPN13 | c.1995G>A p.L665= | Silent (SNP) | VAF 27/77 reads (35%) | called by muse, mutect2, varscan2
- CBLC | c.477C>T p.F159= | Silent (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- CBLIF | c.1128C>T p.I376= | Silent (SNP) | VAF 40/132 reads (30%) | catalogued as rs377061367; called by muse, mutect2, varscan2
- CD9 | c.639C>T p.F213= | Silent (SNP) | VAF 29/128 reads (23%) | called by muse, mutect2, varscan2
- CDH16 | c.81G>A p.V27= | Silent (SNP) | VAF 6/34 reads (18%) | called by muse, varscan2
- CELSR2 | c.7914C>T p.S2638= | Silent (SNP) | VAF 14/60 reads (23%) | called by muse, mutect2, varscan2
- CELSR3 | c.3804G>A p.E1268= | Silent (SNP) | VAF 18/26 reads (69%) | called by muse, mutect2, varscan2
- CES4A | c.120G>A p.Q40= | Silent (SNP) | VAF 42/133 reads (32%) | catalogued as COSV58651759; called by muse, mutect2, varscan2
- CFAP57 | c.3549G>A p.R1183= (on ENST00000372492 / NM_001378189.1; = p.R1216= on NM_001195831.3) | Silent (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2
- CLPS | c.63C>T p.P21= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs1054340429; called by muse, mutect2
- CLRN3 | c.594C>T p.I198= | Silent (SNP) | VAF 25/52 reads (48%) | catalogued as COSV64098826; called by muse, mutect2, varscan2
- CLVS2 | c.483C>T p.I161= | Silent (SNP) | VAF 14/48 reads (29%) | called by muse, mutect2, varscan2
- CMYA5 | c.2460C>T p.S820= | Silent (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2, varscan2
- CMYA5 | c.9894G>A p.Q3298= | Silent (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2, varscan2
- CNNM1 | c.648G>A p.G216= | Silent (SNP) | VAF 7/16 reads (44%) | called by muse, mutect2, varscan2
- CNTN1 | c.144C>T p.I48= | Silent (SNP) | VAF 16/72 reads (22%) | called by muse, varscan2
- CNTNAP4 | c.3174G>A p.V1058= | Silent (SNP) | VAF 14/70 reads (20%) | called by muse, mutect2, varscan2
- COL11A1 | c.3528G>A p.Q1176= | Silent (SNP) | VAF 23/92 reads (25%) | catalogued as COSV100614692, COSV62178697; called by muse, mutect2, varscan2
- COL24A1 | c.4845C>T p.T1615= | Silent (SNP) | VAF 33/129 reads (26%) | catalogued as rs754889472; called by muse, mutect2, varscan2
- COL4A1 | c.3822A>T p.P1274= | Silent (SNP) | VAF 26/104 reads (25%) | called by muse, mutect2, varscan2
- COL6A1 | c.696C>T p.I232= | Silent (SNP) | VAF 52/215 reads (24%) | catalogued as rs139148709; ClinVar: conflicting interpretations of pathogenicity; called by muse, varscan2
- COQ10B | c.168T>A p.P56= | Silent (SNP) | VAF 38/104 reads (37%) | called by muse, mutect2
- CSMD3 | c.4602C>T p.P1534= (on ENST00000297405 / NM_001363185.1; = p.P1430= on NM_052900.3) | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs746629796; called by muse, mutect2, varscan2
- CUBN | c.6231C>T p.S2077= | Silent (SNP) | VAF 46/169 reads (27%) | called by muse, mutect2, varscan2
- CX3CR1 | c.873C>T p.L291= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs746655665; called by mutect2, varscan2
- CYBB | c.6G>A p.G2= | Silent (SNP) | VAF 39/77 reads (51%) | called by muse, mutect2, varscan2
- CYP2A13 | c.867G>A p.K289= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as rs370470188; called by muse, mutect2, varscan2
- CYP3A43 | c.573G>A p.V191= | Silent (SNP) | VAF 10/51 reads (20%) | called by muse, mutect2, varscan2
- CYP4F11 | c.441C>T p.H147= | Silent (SNP) | VAF 10/39 reads (26%) | called by muse, mutect2, varscan2
- DAAM2 | c.1599C>T p.S533= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs1177835604; called by muse, mutect2, varscan2
- DAGLA | c.1254C>T p.P418= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as rs755767901, COSV57195167; called by muse, mutect2, varscan2
- DCAF4L2 | c.366C>T p.V122= | Silent (SNP) | VAF 36/117 reads (31%) | catalogued as rs1245950323, COSV60483495; called by muse, mutect2, varscan2
- DCDC2B | c.666G>A p.R222= | Silent (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2, varscan2
- DCLK2 | c.579C>T p.F193= | Silent (SNP) | VAF 44/125 reads (35%) | catalogued as COSV99652593; called by muse, mutect2, varscan2
- DGKG | c.1881G>A p.A627= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs777457614, COSV53972971; called by muse, mutect2, varscan2
- DNAH9 | c.12396G>A p.G4132= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as rs768307083; called by muse, mutect2, varscan2
- DOCK9 | c.4356C>T p.F1452= (on ENST00000376460 / NM_001366676.2; = p.F1453= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as rs1400133564; called by muse, mutect2, varscan2
- DPPA3 | c.207A>C p.A69= | Silent (SNP) | VAF 52/159 reads (33%) | called by muse, mutect2, varscan2
- DRD5 | c.306G>A p.E102= | Silent (SNP) | VAF 30/114 reads (26%) | catalogued as rs769659017; called by muse, mutect2, varscan2
- DYDC2 | c.66G>A p.A22= | Silent (SNP) | VAF 20/34 reads (59%) | catalogued as rs762611982, COSV55472360; called by muse, mutect2, varscan2
- DYNC2H1 | c.7131C>T p.F2377= | Silent (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- EFHC2 | c.1212C>T p.L404= | Silent (SNP) | VAF 23/43 reads (53%) | called by muse, mutect2, varscan2
- EIF2AK4 | c.156C>T p.P52= | Silent (SNP) | VAF 19/38 reads (50%) | called by muse, mutect2, varscan2
- EIF6 | c.615C>T p.F205= | Silent (SNP) | VAF 54/159 reads (34%) | called by muse, mutect2, varscan2
- ENAM | c.2487G>A p.L829= | Silent (SNP) | VAF 12/50 reads (24%) | called by muse, mutect2, varscan2
- ENOX1 | c.1506G>A p.K502= | Silent (SNP) | VAF 18/62 reads (29%) | called by muse, mutect2, varscan2
- EPB41L3 | c.576C>T p.D192= | Silent (SNP) | VAF 15/94 reads (16%) | called by muse, mutect2, varscan2
- EPHA2 | c.2340C>T p.P780= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs1469123898; called by muse, mutect2, varscan2
- EPHB6 | c.126G>A p.E42= | Silent (SNP) | VAF 33/113 reads (29%) | catalogued as rs747647138; called by muse, mutect2, varscan2
- ERBB3 | c.1098C>T p.T366= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs747748100; called by muse, mutect2, varscan2
- EXOC7 | c.1392C>T p.L464= (on ENST00000335146 / NM_001145297.4; = p.L382= on NM_015219.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 39/115 reads (34%) | catalogued as rs373896817; called by muse, mutect2, varscan2
- F13B | c.1071G>A p.G357= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as rs775799552, COSV66372121; called by muse, mutect2, varscan2
- FAM124A | c.430C>T p.L144= (on ENST00000322475 / NM_001242312.2; = p.L180= on NM_145019.4) | Silent (SNP) | VAF 17/47 reads (36%) | called by muse, mutect2, varscan2
- FAM222A | c.201C>T p.I67= | Silent (SNP) | VAF 57/147 reads (39%) | called by muse, mutect2, varscan2
- FAM83H | c.2754C>T p.P918= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs782030376; called by muse, mutect2, varscan2
- FBLN7 | c.507C>T p.N169= | Silent (SNP) | VAF 24/56 reads (43%) | called by muse, mutect2, varscan2
- FBP2 | c.864C>T p.I288= | Silent (SNP) | VAF 6/10 reads (60%) | called by muse, mutect2
- FBXO43 | c.903T>G p.T301= | Silent (SNP) | VAF 34/101 reads (34%) | called by muse, mutect2, varscan2
- FBXW9 | c.1254C>T p.S418= (on ENST00000587955; = p.S398= on NM_032301.3) | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs993470140, COSV100981931; called by muse, mutect2, varscan2
- FCGBP | c.5442C>T p.L1814= | Silent (SNP) | VAF 34/67 reads (51%) | catalogued as rs1163901879; called by muse, mutect2, varscan2
- FLG2 | c.4413G>A p.Q1471= | Silent (SNP) | VAF 27/130 reads (21%) | called by muse, mutect2, varscan2
- FLG2 | c.927A>G p.Q309= | Silent (SNP) | VAF 18/97 reads (19%) | catalogued as rs780609203; called by muse, mutect2, varscan2
- FLT3 | c.1659C>T p.L553= | Silent (SNP) | VAF 19/89 reads (21%) | catalogued as COSV54061706; called by muse, mutect2, varscan2
- FMN1 | c.3234C>T p.F1078= (on ENST00000616417 / NM_001277313.2; = p.F855= on NM_001103184.4) | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as rs865986556, COSV100569259; called by muse, mutect2, varscan2
361 further variants in this file (0 protein-altering or splice-affecting, 225 silent, 136 other) are not listed here.
